MMRF case MMRF_2554 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2695fb06-0944-4f77-bae9-8230c38c8d0a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 271 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.6 years (23,949 days); ISS stage: I; Days to last known disease status: 271 days; Days to last follow up: 271 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 271.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.555 mg/dL; Immunoglobulin G 27.9 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.34 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37.5 g/L; Total Protein 8.4 g/dL; Glucose 9.02 mmol/L; C-Reactive Protein 0.4 mg/dL.
- Day 102 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 5.67 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 496 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.55 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 9.68 mmol/L.
- Day 200 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.116 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.03 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 1.78 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 9.63 mmol/L.

Other clinical attributes
- Day 1: Weight: 62 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2554_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2554_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
